Somatic mutation profile of tumor specimen ALCH-B3ZL-TTR1-A (aliquot ALCH-B3ZL-TTR1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B3ZL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,038 days).
Specimen ALCH-B3ZL-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd9581b2-363a-4f03-be33-d4d8cbd51ee4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZL-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZL-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15e4dbb2-b157-4cba-a89f-5d9fdd2e206c

The open-access MAF lists 210 somatic variants for this specimen: 138 protein-altering or splice-affecting, 38 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 38, Intron 13, Nonsense Mutation 10, 3'UTR 7, Frame Shift Del 6, 5'UTR 6, 3'Flank 4, RNA 4, Splice Region 2, Translation Start Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC1 | c.2524C>T p.Q842* | Nonsense Mutation (SNP) | VAF 86/457 reads (19%) | catalogued as rs1447417010, BM1382815, COSV100052365; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VARS1 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 36/156 reads (23%) | catalogued as rs763777257, COSV65155930; ClinVar: pathogenic; called by muse, varscan2
- ANKAR | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.707); catalogued as rs1297583069, COSV99854900; called by muse, mutect2, varscan2
- APOE | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs1459489355; called by muse, mutect2, varscan2
- ATP13A5 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.101); catalogued as COSV100665041; called by muse, varscan2
- ATRX | c.3814G>A p.A1272T | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64873515; called by muse, mutect2, varscan2
- ATXN2L | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs768828627, COSV57376149; called by muse, mutect2
- C3 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.634); catalogued as COSV55571320; called by muse, mutect2, varscan2
- CDH2 | c.1483C>A p.P495T | Missense Mutation (SNP) | VAF 63/362 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs200059562; called by muse, mutect2, varscan2
- FIG4 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs372497846; called by muse, mutect2, varscan2
- FSHR | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 34/393 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100437362; called by muse, mutect2
- GRP | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as COSV99900890; called by muse, mutect2, varscan2
- IGKV2D-26 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768027277; called by muse, mutect2, varscan2
- KIAA1217 | c.5193A>G p.I1731M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV56818595; called by muse, mutect2, varscan2
- KRT2 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100548673; called by muse, mutect2, varscan2
- LEFTY2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745994230; called by muse, varscan2
- MARS1 | c.2326C>G p.P776A | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs113090086; called by muse, mutect2, varscan2
- MROH5 | c.2090G>C p.R697T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.236); catalogued as rs373832897; called by muse, mutect2, varscan2
- MUC5AC | c.130C>G p.P44A | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.14); catalogued as COSV100650677; called by muse, mutect2, varscan2
- MUC5B | c.14923C>G p.Q4975E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV101500698; called by muse, mutect2, varscan2
- NAV3 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1005877698, COSV57058762; called by muse, mutect2
- PCLO | c.5894A>G p.Y1965C | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs773714754; called by muse, mutect2, varscan2
- PEAK3 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1315300075; called by muse, mutect2, varscan2
- PGR | c.1907-6C>T | Splice Region (SNP) | VAF 12/60 reads (20%) | catalogued as rs751535093; called by muse, mutect2, varscan2
- PIGU | c.704G>C p.G235A | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.514); catalogued as rs760059464; called by muse, mutect2, varscan2
- POM121 | c.2147C>G p.P716R (on ENST00000434423; = p.P451R on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs782055214; called by muse, mutect2, varscan2
- RBL2 | c.3347G>C p.R1116T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100043156; called by muse, mutect2, varscan2
- RIMS2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 36/614 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372575949, COSV68481666; called by muse, mutect2
- RLF | c.4765G>C p.V1589L | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs757684233; called by muse, mutect2, varscan2
- ROS1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 80/269 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.677); catalogued as COSV100877857; called by muse, mutect2, varscan2
- SLC35B4 | c.450G>C p.E150D | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV65984677; called by muse, mutect2, varscan2
- SLITRK3 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.269); catalogued as rs748228388, COSV53845343; called by muse, mutect2, varscan2
- SNTG2 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57994567; called by muse, mutect2, varscan2
- STK11 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as CM163275, COSV58820732, COSV58830552; called by muse, mutect2, varscan2
- TAS1R3 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs775545181; called by muse, mutect2, varscan2
- TTN | c.28498G>A p.E9500K (on ENST00000591111; = p.E8573K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/101 reads (15%) | PolyPhen benign (0.274); catalogued as COSV59982357; called by muse, varscan2
- VARS1 | c.2348-3C>A | Splice Region (SNP) | VAF 28/96 reads (29%) | catalogued as rs112783854; called by muse, mutect2, varscan2
- ABCC2 | c.1352C>G p.S451C | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ACACA | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ADGRV1 | c.6515C>G p.S2172* | Nonsense Mutation (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- ASXL3 | c.431A>T p.K144M | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRD7 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, varscan2
- CACNA1E | c.3357_3382del p.E1119Dfs*29 | Frame Shift Del (DEL) | VAF 30/168 reads (18%) | called by mutect2, pindel
- CASP8 | c.404A>G p.D135G (on ENST00000432109 / NM_033355.3; = p.D167G on NM_001228.4) | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- CD248 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CGN | c.3421G>T p.V1141F | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- CIITA | c.222C>G p.N74K | Missense Mutation (SNP) | VAF 88/307 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, varscan2
- CLCNKA | c.362_364del p.S121_G122delins* | Nonsense Mutation (DEL) | VAF 79/242 reads (33%) | called by mutect2, pindel, varscan2
- CNOT3 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COX18 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CPNE1 | c.391G>C p.A131P (on ENST00000352393; = p.A136P on NM_003915.5) | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CROCC2 | c.2393T>A p.L798H | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CSMD1 | c.7571A>T p.E2524V (on ENST00000520002; = p.E2523V on NM_033225.6) | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CUX1 | c.334G>A p.E112K (on ENST00000292535 / NM_181552.4; = p.E123K on NM_001913.5) | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- CYP2R1 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DCUN1D5 | c.89A>C p.Y30S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DENND3 | c.2713G>A p.D905N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.218); called by muse, varscan2
- DNMT3B | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- DOCK11 | c.5545G>C p.E1849Q | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ELN | c.1813C>G p.Q605E | Missense Mutation (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- FAM228B | c.287T>G p.V96G | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FBXL17 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- FLOT1 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FNBP1 | c.464T>A p.F155Y | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- FRAS1 | c.8917A>C p.N2973H | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GDF2 | c.670A>C p.N224H | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- GPR162 | c.813C>A p.N271K | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- GTF2IRD2 | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IL17RA | c.1599C>G p.Y533* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- IL21R | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- ITGAV | c.3109C>T p.Q1037* | Nonsense Mutation (SNP) | VAF 40/367 reads (11%) | called by muse, mutect2, varscan2
- KIAA2026 | c.2872A>C p.N958H | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2
- LETM1 | c.228del p.R76Sfs*7 | Frame Shift Del (DEL) | VAF 60/218 reads (28%) | called by mutect2, pindel, varscan2
- LRP11 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRP1B | c.4989A>T p.L1663F | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- MCM9 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MEGF11 | c.3092G>A p.R1031K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MFSD4B | c.81C>A p.C27* (on ENST00000368847; = p.Q123K on NM_153369.4) | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2
- MIER1 | c.511G>C p.D171H (on ENST00000355356 / NM_001077701.3; = p.D188H on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MSH5 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MSS51 | c.292A>T p.M98L | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV1 | c.5408C>G p.S1803* | Nonsense Mutation (SNP) | VAF 68/265 reads (26%) | called by muse, mutect2, varscan2
- NFIB | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- NOVA1 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 326/470 reads (69%) | SIFT tolerated (0.58); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR51D1 | c.223_260del p.F75Lfs*47 | Frame Shift Del (DEL) | VAF 18/180 reads (10%) | called by mutect2, pindel
- OR51Q1 | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- P2RX3 | c.1068G>C p.K356N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- PCDH15 | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 64/463 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PHKA2 | c.3428C>T p.A1143V | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PLEC | c.13877C>G p.S4626C (on ENST00000322810 / NM_201380.4; = p.S4516C on NM_000445.5) | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEKHG2 | c.805G>C p.A269P | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POGZ | c.3562G>C p.D1188H | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- POLA1 | c.2405T>A p.I802N | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKD2 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRTG | c.2778del p.K927Sfs*3 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | called by mutect2, pindel, varscan2
- PWWP3B | c.1430G>T p.R477I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PXDC1 | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PYHIN1 | c.1312A>T p.T438S | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.092); called by muse, mutect2
- QRSL1 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2
- RFX5 | c.438C>G p.I146M | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RMC1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF10 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- RSPH4A | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- S100A14 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 30/132 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SAMD4A | c.747G>C p.L249F | Missense Mutation (SNP) | VAF 122/352 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SAMD8 | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SENP6 | c.2553G>C p.K851N | Missense Mutation (SNP) | VAF 99/406 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINE1 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGO2 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SIPA1L2 | c.2584del p.R862Gfs*22 | Frame Shift Del (DEL) | VAF 29/119 reads (24%) | called by mutect2, pindel, varscan2
- SLCO2B1 | c.65C>A p.T22K | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SP4 | c.1391C>A p.S464* | Nonsense Mutation (SNP) | VAF 33/333 reads (10%) | called by muse, mutect2, varscan2
- SPTA1 | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 95/511 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- SPTAN1 | c.4327C>A p.Q1443K | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SSR4 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- SSX1 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRN | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SURF1 | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SYNM | c.1529G>C p.R510T | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- TAPBP | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.959); called by muse, mutect2
- TENM1 | c.7378C>G p.L2460V | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TET1 | c.6118C>T p.H2040Y | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TMEM239 | c.550A>C p.M184L (on ENST00000361033 / NM_001318207.1; = p.M141L on NM_001167670.3) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); called by mutect2, varscan2
- TRIM27 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRIM51GP | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2
- TSPOAP1 | c.3700-1G>A p.X1234_splice | Splice Site (SNP) | VAF 27/52 reads (52%) | called by muse, varscan2
- TTLL4 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.103010del p.G34337Dfs*7 (on ENST00000591111; = p.G26913Dfs*7 on NM_003319.4) | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by pindel, varscan2
- UFL1 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- WDR37 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- XPO5 | c.1308C>G p.F436L | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZC3H13 | c.344A>G p.E115G | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF273 | c.177G>C p.Q59H | Missense Mutation (SNP) | VAF 101/389 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF696 | c.576G>C p.Q192H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF774 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ZNF81 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF862 | c.3509G>C p.*1170Sext*27 | Nonstop Mutation (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2
- ZSWIM1 | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); called by muse, mutect2
- AKTIP | c.219C>T p.F73= | Silent (SNP) | VAF 53/179 reads (30%) | called by muse, mutect2, varscan2
- ALMS1 | c.975G>T p.S325= | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as rs370267673; called by muse, mutect2, varscan2
- ALPL | c.786A>G p.R262= | Silent (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- ARVCF | c.1674G>C p.V558= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV99599577; called by muse, mutect2, varscan2
- ATP9A | c.18G>C p.P6= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- DMD | c.7425C>T p.F2475= | Silent (SNP) | VAF 62/365 reads (17%) | catalogued as CD148480, COSV58918294; called by muse, mutect2, varscan2
- EGR3 | c.1068C>G p.L356= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- ELK4 | c.216C>T p.I72= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, varscan2
- FBXL18 | c.2109C>G p.T703= | Silent (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- FREM1 | c.5719A>C p.R1907= | Silent (SNP) | VAF 22/244 reads (9%) | called by muse, mutect2
- FSIP2 | c.5970C>T p.N1990= | Silent (SNP) | VAF 55/260 reads (21%) | catalogued as rs900738972; called by muse, mutect2, varscan2
- GRAMD1B | c.1312C>T p.L438= | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- GRM5 | c.2265C>A p.T755= | Silent (SNP) | VAF 9/167 reads (5%) | catalogued as COSV100555108; called by muse, mutect2
- HIVEP3 | c.4188G>C p.L1396= | Silent (SNP) | VAF 41/110 reads (37%) | called by muse, mutect2, varscan2
- KRT83 | c.1002C>A p.I334= | Silent (SNP) | VAF 40/272 reads (15%) | called by muse, mutect2
- LARP1B | c.1689G>A p.L563= | Silent (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- MIB2 | c.3156C>G p.L1052= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV61542502; called by muse, mutect2, varscan2
- MICU3 | c.54C>T p.L18= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- MSH5 | c.1830C>T p.F610= | Silent (SNP) | VAF 55/220 reads (25%) | catalogued as COSV65173240; called by muse, mutect2, varscan2
- NT5C2 | c.1206C>G p.L402= | Silent (SNP) | VAF 53/251 reads (21%) | catalogued as rs747393327; called by muse, mutect2, varscan2
- NUP214 | c.2518C>T p.L840= | Silent (SNP) | VAF 36/484 reads (7%) | catalogued as rs1412804119; called by muse, mutect2
- OR52K1 | c.597C>T p.I199= | Silent (SNP) | VAF 68/204 reads (33%) | catalogued as COSV56904778; called by muse, mutect2, varscan2
- OR6C1 | c.306C>T p.F102= | Silent (SNP) | VAF 30/238 reads (13%) | called by muse, mutect2, varscan2
- OR8A1 | c.711C>T p.F237= | Silent (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.180G>C p.A60= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV53938738; called by muse, mutect2, varscan2
- PIK3C2A | c.1092G>A p.L364= | Silent (SNP) | VAF 50/265 reads (19%) | called by muse, mutect2, varscan2
- PIK3C3 | c.1950C>T p.I650= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1467945486; called by muse, mutect2, varscan2
- PLEKHG2 | c.2913T>C p.T971= | Silent (SNP) | VAF 23/151 reads (15%) | called by muse, mutect2, varscan2
- PLXNA4 | c.225C>A p.S75= | Silent (SNP) | VAF 55/245 reads (22%) | called by muse, mutect2, varscan2
- POLR3B | c.3366C>T p.I1122= | Silent (SNP) | VAF 35/334 reads (10%) | catalogued as COSV57277834; called by muse, mutect2, varscan2
- PRKD2 | c.975G>A p.P325= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs766006065, COSV99354334; called by muse, mutect2, varscan2
- RAB5IF | c.90G>A p.R30= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs1401149056; called by muse, mutect2, varscan2
- SCAPER | c.546G>C p.V182= | Silent (SNP) | VAF 80/278 reads (29%) | called by muse, mutect2, varscan2
- SLC39A4 | c.1752G>A p.E584= (on ENST00000301305 / NM_001374839.1; = p.E559= on NM_017767.3) | Silent (SNP) | VAF 35/118 reads (30%) | called by muse, mutect2, varscan2
- SNRNP48 | c.564C>T p.L188= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- STRAP | c.75C>T p.I25= | Silent (SNP) | VAF 24/163 reads (15%) | called by muse, mutect2, varscan2
- TAS1R3 | c.1368G>A p.L456= | Silent (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- TRBV23-1 | c.318G>T p.T106= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- AFP | c.*37C>A | 3'UTR (SNP) | VAF 52/183 reads (28%) | called by muse, mutect2, varscan2
- AK2 | c.*2613T>C | 3'UTR (SNP) | VAF 42/117 reads (36%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73831117 G>A | 3'Flank (SNP) | VAF 62/198 reads (31%) | called by muse, mutect2, varscan2
- AMPD1 | c.315-62C>G | Intron (SNP) | VAF 69/284 reads (24%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.355+27144G>A | Intron (SNP) | VAF 27/189 reads (14%) | catalogued as rs751445305; called by muse, mutect2, varscan2
- CALM2 | c.-25C>T | 5'UTR (SNP) | VAF 13/151 reads (9%) | catalogued as rs1474682656, COSV99700766, COSV99701005; called by muse, mutect2, varscan2
- CDH13 | c.-1_1del | 5'UTR (DEL) | VAF 34/153 reads (22%) | called by mutect2, pindel, varscan2
- EPDR1 | c.-52C>G | 5'UTR (SNP) | VAF 30/96 reads (31%) | catalogued as COSV99554579; called by muse, mutect2, varscan2
- HGSNAT | c.1542+19_1542+58del | Intron (DEL) | VAF 51/192 reads (27%) | called by mutect2, pindel
- IGFLR1 | c.-39G>T | 5'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- IGKV1D-33 | c.-21C>T | 5'UTR (SNP) | VAF 20/115 reads (17%) | called by muse, varscan2
- KANSL2 | c.-10+211C>G | Intron (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- KCNQ1 | c.*134C>A | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- MASP1 | c.1303+5632G>A | Intron (SNP) | VAF 49/250 reads (20%) | called by muse, mutect2, varscan2
- NME8 | c.1545-20G>C | Intron (SNP) | VAF 24/214 reads (11%) | called by muse, mutect2, varscan2
- NPRL2 | c.684-9C>G | Intron (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- PIPSL | n.630C>G | RNA (SNP) | VAF 32/214 reads (15%) | called by muse, mutect2, varscan2
- PLEKHA7 | chr11:16783761 C>G | 3'Flank (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991792 A>T | 3'Flank (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- RNU7-115P | chr17:64824710 C>T | 3'Flank (SNP) | VAF 112/381 reads (29%) | catalogued as rs1258104918; called by muse, mutect2, varscan2
- ROGDI | c.117+199G>A | Intron (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- SGK2 | c.1120-1554G>C | Intron (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- SHROOM4 | c.*3C>T | 3'UTR (SNP) | VAF 104/338 reads (31%) | called by muse, mutect2, varscan2
- SLC8A1 | c.1915+566G>A | Intron (SNP) | VAF 57/236 reads (24%) | called by muse, mutect2, varscan2
- SMIM8 | n.563G>C | RNA (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2
- SOHLH1 | c.*660C>G | 3'UTR (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.2785C>T | RNA (SNP) | VAF 18/113 reads (16%) | catalogued as rs770524269; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 13/58 reads (22%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TMEM59L | c.664+305C>T | Intron (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+1108G>C | Intron (SNP) | VAF 22/108 reads (20%) | catalogued as COSV60251485; called by muse, mutect2, varscan2
- UQCRB | c.*2785G>C | 3'UTR (SNP) | VAF 53/193 reads (27%) | called by muse, mutect2, varscan2
- UQCRB | c.*591A>G | 3'UTR (SNP) | VAF 17/229 reads (7%) | called by muse, mutect2
- ZNF527 | c.257-3421del | Intron (DEL) | VAF 22/76 reads (29%) | called by mutect2, pindel, varscan2
- ZNF542P | n.856A>G | RNA (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
